Somatic mutation profile of tumor specimen MP2PRT-PAVYHJ-TMP1-A (aliquot MP2PRT-PAVYHJ-TMP1-A-1-0-D-A821-36) from MP2PRT case MP2PRT-PAVYHJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.5 years (1,267 days).
Specimen MP2PRT-PAVYHJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1240d38f-287f-43e3-897f-7f19000d9ad9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVYHJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVYHJ-NB1-A-1-0-D-A821-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bb94ef34-66d9-4474-a135-c8dc80838e6c

The open-access MAF lists 12 somatic variants for this specimen: 12 protein-altering or splice-affecting.
By variant classification: Missense Mutation 11, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.176C>A p.A59E | Missense Mutation (SNP) | VAF 30/529 reads (6%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55568979, COSV55604554, COSV55904854; called by muse, mutect2
- AAMP | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 123/413 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.648); catalogued as rs894396135; called by muse, mutect2, varscan2
- B3GNTL1 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 129/498 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs192413231; called by muse, mutect2, varscan2
- MEI1 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 47/243 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs757613618, COSV55902114, COSV55902737; called by muse, mutect2, varscan2
- PLEKHG3 | c.1676G>A p.R559Q (on ENST00000394691; = p.R615Q on NM_001308147.2) | Missense Mutation (SNP) | VAF 34/752 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.232); catalogued as rs750439742, COSV55981704; called by muse, mutect2
- SLC5A3 | c.1888G>A p.A630T | Missense Mutation (SNP) | VAF 42/562 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as rs751408052, COSV104424000; called by muse, mutect2
- SMARCAL1 | c.2852C>T p.T951M | Missense Mutation (SNP) | VAF 45/153 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.634); catalogued as rs751084968, COSV61921782; called by muse, mutect2, varscan2
- UBXN11 | c.667G>A p.G223S (on ENST00000374221 / NM_183008.2; = p.G190S on NM_145345.2) | Missense Mutation (SNP) | VAF 131/367 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.2); catalogued as rs763898877; called by muse, mutect2, varscan2
- USP8 | c.2189_2199del p.E730Afs*8 | Frame Shift Del (DEL) | VAF 19/180 reads (11%) | catalogued as rs148769606; called by mutect2, varscan2
- AC004593.2 | c.244G>C p.A82P | Missense Mutation (SNP) | VAF 15/191 reads (8%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.114); called by muse, mutect2
- CASQ2 | c.611C>A p.A204E | Missense Mutation (SNP) | VAF 49/138 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- ZNF462 | c.4450G>A p.G1484S | Missense Mutation (SNP) | VAF 114/327 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
